Gene-level copy-number profile of tumor specimen TARGET-10-PATWXC-09A from TARGET case TARGET-10-PATWXC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.0 years (5,488 days).
Specimen TARGET-10-PATWXC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.674199f9-59a7-56b9-bf8c-b986a67e6a66.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATWXC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 413 have no estimate.
https://portal.gdc.cancer.gov/files/385e2f92-e65c-4c46-9672-4d977b870b79

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 169; copy number 1: 2,430; copy number 2: 57,278; copy number 3: 316; copy number 5: 12; copy number 8: 5.

Homozygous deletions (total copy number 0; autosomes only): 169 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,276,318, 4 genes (within-gene range 0–2): TRGC1, TRGJ1, TRGJP, TRGJP1.
- chr7:142,380,806–142,793,368, 63 genes (broad region; genes not listed).
- chr9:21,802,636–22,029,594, 8 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene: AL449423.1.
- chr14:22,096,032–22,543,240, 93 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:97,113,153–97,264,521, 1 gene, copy number 5 (within-gene range 2–5): ANKRD36.
- chr8:150,584–202,897, 5 genes, copy number 8: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1.
- chr10:46,233,885–46,537,864, 10 genes, copy number 5 (within-gene range 2–5): ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R.
- chr11:4,954,772–4,955,713, 1 gene, copy number 5: OR51A2.

Autosomal genes at a single copy (total copy number 1): 46. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
